Somatic mutation profile of tumor specimen C3L-04760-01 (aliquot CPT0258200006) from CPTAC case C3L-04760, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 83.1 years (30,367 days).
Specimen C3L-04760-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d2bf447-e401-41ae-9cc3-247138e5234e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04760-31 (Blood Derived Normal), aliquot CPT0258300002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3f7b23e-dacd-4427-9bb9-e4555af212b2

The open-access MAF lists 542 somatic variants for this specimen: 364 protein-altering or splice-affecting, 155 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 328, Silent 155, Nonsense Mutation 25, Intron 14, Splice Region 6, 5'Flank 3, 3'Flank 3, In Frame Del 2, 3'UTR 2, Translation Start Site 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/276 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/275 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HSD17B4 | c.1591C>T p.R531C (on ENST00000414835 / NM_001199291.3; = p.R506C on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 111/322 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs766199971, CM060031; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 152/404 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1057519732, COSV61068297; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1723C>T p.Q575* | Nonsense Mutation (SNP) | VAF 88/240 reads (37%) | catalogued as rs587778864, CM961232, COSV57303654; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.5759T>C p.I1920T | Missense Mutation (SNP) | VAF 124/326 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV101037310; called by muse, mutect2, varscan2
- ABCA6 | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 85/274 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs757237731; called by muse, mutect2, varscan2
- ABCB9 | c.2043C>T p.I681= (on ENST00000280560 / NM_019625.4; = p.I638= on NM_019624.3) | Splice Region (SNP) | VAF 116/307 reads (38%) | catalogued as COSV54893874; called by muse, mutect2, varscan2
- ADAM17 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 114/332 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs865879773, COSV60397978; called by muse, mutect2, varscan2
- ADAMTS5 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 91/250 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1286298815, COSV53175922; called by muse, mutect2, varscan2
- ADAMTS6 | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 123/259 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.168); catalogued as rs1434865692, COSV100068431; called by muse, mutect2, varscan2
- ADCY2 | c.1687G>T p.G563W | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100604131, COSV57860132; called by muse, mutect2, varscan2
- AHNAK | c.9881C>T p.S3294F | Missense Mutation (SNP) | VAF 142/379 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57215164; called by muse, mutect2, varscan2
- ANKEF1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 146/425 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.654); catalogued as rs1173259468, COSV65692606; called by muse, mutect2, varscan2
- ANKFN1 | c.3848C>T p.P1283L (on ENST00000653862; = p.P1136L on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/308 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.555); catalogued as rs1158777482; called by muse, mutect2, varscan2
- ARHGAP39 | c.2504C>T p.P835L | Missense Mutation (SNP) | VAF 117/411 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs758491166; called by muse, mutect2, varscan2
- ARL14EPL | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 160/441 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs908654265; called by muse, mutect2, varscan2
- ATP2B2 | c.1364C>T p.S455L (on ENST00000352432; = p.S421L on NM_001683.5) | Missense Mutation (SNP) | VAF 104/319 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1198836153, COSV100660404; called by muse, mutect2, varscan2
- BAG6 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 175/447 reads (39%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.98); catalogued as rs1412003019; called by muse, mutect2, varscan2
- BAHD1 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 213/604 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as rs756512138; called by muse, mutect2, varscan2
- BCAM | c.507C>T p.I169= | Splice Region (SNP) | VAF 103/284 reads (36%) | catalogued as rs1014808418, COSV54305037; called by muse, mutect2, varscan2
- BRAF | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 170/468 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.941); catalogued as COSV56188894; called by muse, mutect2, varscan2
- BSN | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 271/678 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56527161; called by muse, mutect2, varscan2
- BTAF1 | c.4391G>A p.R1464Q | Missense Mutation (SNP) | VAF 155/255 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs966281593, COSV56429578; called by muse, mutect2, varscan2
- BTBD11 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 181/536 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.048); catalogued as rs376834648; called by muse, mutect2, varscan2
- BUD13 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 141/398 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs149672740; called by muse, mutect2, varscan2
- C12orf50 | c.973A>G p.K325E | Missense Mutation (SNP) | VAF 146/370 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); catalogued as COSV53895158; called by muse, mutect2, varscan2
- C1GALT1 | c.1080A>T p.L360F | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as COSV56178782; called by muse, mutect2, varscan2
- C1orf158 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 109/296 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs746650779; called by muse, mutect2, varscan2
- C2orf80 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 63/256 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs138681111, COSV58017866; called by muse, mutect2, varscan2
- CCT6B | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 88/253 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1487072755; called by muse, mutect2, varscan2
- CD2 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 163/413 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65644780; called by muse, mutect2, varscan2
- CD2 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 189/537 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as rs370570850; called by muse, mutect2, varscan2
- CD96 | c.1148C>T p.S383F (on ENST00000283285 / NM_198196.3; = p.S367F on NM_005816.5) | Missense Mutation (SNP) | VAF 75/269 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV51913647; called by muse, mutect2, varscan2
- CLASP1 | c.3422C>T p.P1141L | Missense Mutation (SNP) | VAF 140/404 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs1357964424, COSV55319216; called by muse, mutect2, varscan2
- CLIP4 | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 83/269 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1208638129, COSV99065486; called by muse, mutect2
- CNGA3 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 195/550 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs144627146; called by muse, mutect2, varscan2
- CNGB3 | c.2051G>A p.G684E | Missense Mutation (SNP) | VAF 161/408 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.132); catalogued as rs759584325; called by muse, mutect2, varscan2
- COL11A1 | c.5069C>T p.S1690F | Missense Mutation (SNP) | VAF 64/201 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV62199099, COSV62200534; called by muse, mutect2, varscan2
- COL16A1 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 146/399 reads (37%) | catalogued as rs779624978; called by muse, mutect2, varscan2
- COL21A1 | c.2102G>A p.G701E | Missense Mutation (SNP) | VAF 97/275 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55152222; called by muse, mutect2, varscan2
- COL5A3 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 125/210 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs780783103, COSV53408632, COSV53416377; called by muse, mutect2, varscan2
- COX10 | c.1021G>C p.G341R | Missense Mutation (SNP) | VAF 175/537 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104376828; called by muse, mutect2, varscan2
- CSMD1 | c.5884C>T p.R1962C (on ENST00000520002; = p.R1961C on NM_033225.6) | Missense Mutation (SNP) | VAF 125/207 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100153139; called by muse, mutect2, varscan2
- CSMD2 | c.9242G>A p.R3081K | Missense Mutation (SNP) | VAF 164/453 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV53908156; called by muse, mutect2, varscan2
- CUBN | c.7459G>A p.G2487R | Missense Mutation (SNP) | VAF 154/274 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV64730925; called by muse, mutect2, varscan2
- DEUP1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 103/250 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV99976858; called by muse, mutect2, varscan2
- DGKI | c.1963G>A p.G655R | Missense Mutation (SNP) | VAF 81/291 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55946803; called by muse, mutect2, varscan2
- DNAH10 | c.7319G>A p.G2440E (on ENST00000409039; = p.G2379E on NM_207437.3) | Missense Mutation (SNP) | VAF 102/347 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs1566018998, COSV69001266; called by muse, mutect2, varscan2
- DNMT3B | c.548G>A p.S183N | Missense Mutation (SNP) | VAF 230/605 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.159); catalogued as COSV52420933; called by muse, mutect2, varscan2
- DSG3 | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 115/323 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs781038848, COSV99934947; called by muse, mutect2, varscan2
- DTHD1 | c.2237G>A p.R746Q (on ENST00000456874; = p.R581Q on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/324 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs1179052199; called by muse, mutect2, varscan2
- EDARADD | c.559C>T p.H187Y (on ENST00000334232 / NM_145861.4; = p.H177Y on NM_080738.4) | Missense Mutation (SNP) | VAF 185/539 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV62061124; called by muse, mutect2, varscan2
- EHMT1 | c.2131C>T p.L711F | Missense Mutation (SNP) | VAF 209/586 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs779593564, COSV58376576; called by muse, mutect2, varscan2
- ENPEP | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 83/268 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54453540, COSV54456180; called by muse, mutect2, varscan2
- EPPK1 | c.3473G>C p.R1158P | Missense Mutation (SNP) | VAF 162/731 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101599805, COSV101599974; called by muse, mutect2, varscan2
- ERICH3 | c.3778G>A p.G1260R | Missense Mutation (SNP) | VAF 196/505 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1470711605; called by muse, mutect2, varscan2
- ESRP1 | c.1615C>T p.R539* | Nonsense Mutation (SNP) | VAF 225/493 reads (46%) | catalogued as COSV64408871; called by muse, mutect2, varscan2
- ESRRA | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 96/275 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99135068; called by muse, mutect2, varscan2
- EZHIP | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 167/227 reads (74%) | SIFT tolerated (0.35); PolyPhen benign (0.081); catalogued as rs1334894799; called by muse, mutect2, varscan2
- FAM135A | c.4414C>T p.R1472C (on ENST00000370479 / NM_001351599.1; = p.R1259C on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 173/459 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1322403675, COSV52059273; called by muse, mutect2, varscan2
- FAT4 | c.10414C>T p.R3472* | Nonsense Mutation (SNP) | VAF 139/366 reads (38%) | catalogued as rs1403984745, COSV58676900; called by muse, mutect2, varscan2
- FBXW10 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 161/659 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as rs750685668; called by muse, mutect2, varscan2
- FBXW10 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 113/347 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as rs1014732931, COSV100111397; called by muse, mutect2, varscan2
- FMNL3 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 175/486 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs1193252775; called by muse, mutect2, varscan2
- FOXD2 | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 173/473 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.011); catalogued as rs1487324841; called by muse, mutect2, varscan2
- FRAS1 | c.5494C>T p.P1832S | Missense Mutation (SNP) | VAF 129/334 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.079); catalogued as rs756681874; called by muse, mutect2, varscan2
- GAL3ST4 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 95/292 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs754323863, COSV57585869; called by muse, mutect2, varscan2
- GAN | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 100/201 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV73721320; called by muse, mutect2, varscan2
- GNAT3 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 150/396 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68068023; called by muse, mutect2, varscan2
- GOLGB1 | c.1973G>A p.G658E | Missense Mutation (SNP) | VAF 138/379 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV61472753; called by muse, mutect2, varscan2
- GOLT1A | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 113/300 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748780832, COSV57643343; called by muse, mutect2, varscan2
- GPR83 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 154/424 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV54718707, COSV54720284; called by muse, mutect2, varscan2
- GRIA1 | c.2022G>A p.R674= | Splice Region (SNP) | VAF 65/188 reads (35%) | catalogued as COSV53587267; called by muse, mutect2, varscan2
- GRM2 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 158/404 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs749107956, COSV56586173; called by muse, mutect2, varscan2
- GRM8 | c.2618G>A p.G873E | Missense Mutation (SNP) | VAF 161/414 reads (39%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.461); catalogued as COSV58807935; called by muse, mutect2, varscan2
- GSTM3 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 112/289 reads (39%) | catalogued as COSV56661905; called by muse, mutect2, varscan2
- GTF3C5 | c.192C>G p.F64L | Missense Mutation (SNP) | VAF 132/383 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV59602020; called by muse, mutect2, varscan2
- HDAC3 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 123/332 reads (37%) | catalogued as rs1293953209, COSV59495227; called by muse, mutect2, varscan2
- HGFAC | c.1202G>A p.R401K | Missense Mutation (SNP) | VAF 210/564 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as rs1214950183; called by muse, mutect2, varscan2
- HOXA6 | c.57C>A p.D19E | Missense Mutation (SNP) | VAF 163/403 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1179915216; called by muse, mutect2, varscan2
- IMPG1 | c.1184T>C p.L395P | Missense Mutation (SNP) | VAF 42/474 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs753090077; called by muse, mutect2
- JAKMIP1 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as COSV51529845, COSV51540667; called by muse, mutect2, varscan2
- KALRN | c.7498C>T p.P2500S (on ENST00000360013 / NM_001024660.4; = p.P803S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 145/415 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs760158908; called by muse, mutect2, varscan2
- KCNJ10 | c.172A>G p.T58A | Missense Mutation (SNP) | VAF 173/488 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63633086; called by muse, mutect2, varscan2
- KRT6C | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 131/263 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as rs1279590825; called by muse, mutect2, varscan2
- KSR2 | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 106/330 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs765242951, COSV56666019; called by muse, mutect2, varscan2
- LILRA1 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 98/383 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as rs777824206, COSV52178121; called by muse, varscan2
- LPA | c.2616G>A p.M872I | Missense Mutation (SNP) | VAF 75/247 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.229); catalogued as COSV60309299; called by muse, mutect2, varscan2
- LRP1B | c.11728G>A p.D3910N | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs369651702, COSV104431924, COSV67221078; called by muse, mutect2, varscan2
- LRRC7 | c.1546G>A p.D516N (on ENST00000651989 / NM_001370785.2; = p.D483N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.437); catalogued as COSV50442528, COSV50591868; called by muse, mutect2, varscan2
- MAGEL2 | c.2810C>T p.P937L | Missense Mutation (SNP) | VAF 180/493 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs761049409; called by muse, mutect2, varscan2
- MAN1C1 | c.1597T>C p.W533R | Missense Mutation (SNP) | VAF 147/439 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460509552; called by muse, mutect2, varscan2
- MARCHF2 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 91/156 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs760320995; called by muse, mutect2, varscan2
- ME1 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 114/281 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV63839643; called by muse, mutect2, varscan2
- MGAM | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 177/498 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.105); catalogued as COSV72073550; called by muse, mutect2, varscan2
- MGAM2 | c.3274G>A p.E1092K | Missense Mutation (SNP) | VAF 106/375 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs947608659; called by muse, mutect2, varscan2
- MINK1 | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 214/629 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs990558398; called by muse, mutect2, varscan2
- MIPEP | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 91/278 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.027); catalogued as COSV66299785, COSV66301026; called by muse, mutect2, varscan2
- MROH2B | c.2500C>T p.R834W | Missense Mutation (SNP) | VAF 150/412 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs368507319; called by muse, mutect2, varscan2
- MYH13 | c.4250C>T p.S1417L | Missense Mutation (SNP) | VAF 202/470 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1290440648, COSV52821712; called by muse, mutect2, varscan2
- MYH13 | c.4138G>A p.E1380K | Missense Mutation (SNP) | VAF 180/582 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs376810508, COSV52821247; called by muse, mutect2
- MYH2 | c.1326G>A p.M442I | Missense Mutation (SNP) | VAF 172/493 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as COSV55443146; called by muse, mutect2, varscan2
- MYH8 | c.2499G>A p.M833I | Missense Mutation (SNP) | VAF 121/334 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs866239257, COSV67966170; called by muse, mutect2, varscan2
- NEB | c.12194C>T p.S4065F | Missense Mutation (SNP) | VAF 154/429 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs745836611; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP7 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 302/794 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60171211; called by muse, mutect2, varscan2
- NUP210L | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 161/476 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as rs770200282, COSV55137827; called by muse, mutect2, varscan2
- NUP214 | c.2454T>G p.H818Q | Missense Mutation (SNP) | VAF 141/329 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs1298402879; called by muse, mutect2, varscan2
- OLAH | c.511G>A p.E171K (on ENST00000378228 / NM_001039702.3; = p.E224K on NM_018324.3) | Missense Mutation (SNP) | VAF 169/293 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as rs1465694432, COSV65493662; called by muse, mutect2, varscan2
- OPN3 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 107/254 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.454); catalogued as COSV59363554; called by muse, mutect2, varscan2
- OR1P1 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 88/216 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1032865441; called by muse, varscan2
- OR4A8 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 101/286 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.076); catalogued as rs763404592; called by muse, mutect2, varscan2
- OR4K13 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 122/382 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV59859036; called by muse, mutect2, varscan2
- OR4K5 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 132/716 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV60003041; called by muse, mutect2, varscan2
- OR52E8 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 108/334 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs146523706, COSV66210619; called by muse, mutect2, varscan2
- OR5H2 | c.322T>C p.S108P | Missense Mutation (SNP) | VAF 146/422 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); catalogued as COSV62350922, COSV62351955; called by muse, mutect2, varscan2
- OR6C76 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 112/351 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as rs1317824796; called by muse, mutect2, varscan2
- OTOGL | c.6763G>A p.E2255K (on ENST00000547103; = p.E2246K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/321 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs762851871; called by muse, mutect2
- PCDHB12 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 269/703 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV53399588; called by muse, mutect2, varscan2
- PCDHB16 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 139/393 reads (35%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.506); catalogued as COSV99032774; called by muse, mutect2, varscan2
- PCDHGA2 | c.2365G>A p.D789N | Missense Mutation (SNP) | VAF 201/508 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as rs1331152315, COSV53918250; called by muse, mutect2, varscan2
- PIWIL4 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 147/351 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as rs199802393; called by muse, mutect2, varscan2
- PKHD1L1 | c.9216G>A p.M3072I | Missense Mutation (SNP) | VAF 110/404 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV65742180; called by muse, mutect2, varscan2
- PLCB4 | c.2198C>T p.T733I | Missense Mutation (SNP) | VAF 171/411 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370308281; called by muse, mutect2, varscan2
- PLD5 | c.676G>A p.V226M (on ENST00000442594; = p.V164M on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 154/421 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV59161320; called by muse, mutect2, varscan2
- PRSS1 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 162/516 reads (31%) | catalogued as COSV61196852; called by muse, varscan2
- PRSS35 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 160/458 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV63800598; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 125/421 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54761532; called by muse, mutect2, varscan2
- RASGRP3 | c.640A>G p.T214A | Missense Mutation (SNP) | VAF 125/354 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as COSV67824164; called by muse, mutect2, varscan2
- RB1 | c.264G>A p.L88= | Splice Region (SNP) | VAF 66/207 reads (32%) | catalogued as CS057979, COSV57305237, COSV57313037, COSV57330181; called by muse, mutect2, varscan2
- RBFOX1 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 150/385 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60986703; called by muse, mutect2, varscan2
- RGS6 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 95/270 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59567017; called by muse, mutect2, varscan2
- RIC3 | c.602G>A p.G201E (on ENST00000309737 / NM_001206671.4; = p.G200E on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 146/408 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867711691, COSV58305183; called by muse, mutect2, varscan2
- RIT2 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 133/405 reads (33%) | catalogued as COSV56295413; called by muse, mutect2, varscan2
- RNF213 | c.3715G>A p.E1239K | Missense Mutation (SNP) | VAF 178/500 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1444613517; called by muse, mutect2, varscan2
- RNF215 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 151/415 reads (36%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.527); catalogued as COSV99306369; called by muse, mutect2, varscan2
- ROS1 | c.6952G>A p.E2318K | Missense Mutation (SNP) | VAF 135/421 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); catalogued as rs768332561, COSV63851171; called by muse, mutect2, varscan2
- ROS1 | c.6797C>T p.T2266M | Missense Mutation (SNP) | VAF 156/419 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs781588795, COSV100877654, COSV63857208; called by muse, mutect2, varscan2
- SALL3 | c.3509C>T p.A1170V | Missense Mutation (SNP) | VAF 205/572 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs533436270, COSV73306302, COSV73306776; called by muse, mutect2, varscan2
- SARM1 | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 87/285 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1555585664; called by muse, mutect2, varscan2
- SBNO1 | c.3268C>T p.R1090C (on ENST00000420886; = p.R1089C on NM_018183.5) | Missense Mutation (SNP) | VAF 107/280 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as rs546657066, COSV57339722; called by muse, mutect2, varscan2
- SCIN | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 98/293 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1200882285, COSV51692101; called by muse, mutect2, varscan2
- SCN9A | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 85/229 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57614790; called by muse, mutect2, varscan2
- SEC14L6 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 111/340 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs976374679; called by muse, mutect2, varscan2
- SEC16B | c.3055C>T p.P1019S | Missense Mutation (SNP) | VAF 129/400 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100381422; called by muse, mutect2, varscan2
- SFTPA2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 130/261 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs767317715, COSV64882540; called by muse, mutect2, varscan2
- SLC12A1 | c.2453G>A p.G818E | Missense Mutation (SNP) | VAF 109/291 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs751250413, COSV66791811; called by muse, mutect2, varscan2
- SLC15A2 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 79/253 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV55197603; called by muse, mutect2, varscan2
- SLC25A4 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 90/278 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as rs755597294; called by muse, mutect2, varscan2
- SLC26A4 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 110/284 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs772817809; called by muse, mutect2, varscan2
- SLC44A5 | c.1559C>T p.S520F | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63763880; called by muse, varscan2
- SLC44A5 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63775851; called by muse, varscan2
- SLC7A11 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 87/282 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54931498, COSV99763468; called by muse, mutect2, varscan2
- SLCO4C1 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 171/507 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as rs752419323; called by muse, mutect2, varscan2
- SLFN12L | c.1666C>T p.R556C (on ENST00000260908 / NM_001363830.1; = p.R574C on NM_001195790.1) | Missense Mutation (SNP) | VAF 102/294 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs966521488; called by muse, varscan2
- SNRNP200 | c.4307C>T p.S1436F | Missense Mutation (SNP) | VAF 149/460 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60495382; called by muse, mutect2, varscan2
- SORL1 | c.1771G>T p.G591W | Missense Mutation (SNP) | VAF 166/467 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52758187; called by muse, mutect2, varscan2
- SPHKAP | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 168/439 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1416078052, COSV100763912; called by muse, mutect2, varscan2
- TACC3 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 196/546 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs1374170639, COSV100508821; called by muse, varscan2
- TBXT | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 117/327 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as COSV51617872; called by muse, mutect2, varscan2
- TECRL | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 93/293 reads (32%) | catalogued as rs1355389485, COSV67086362; called by muse, mutect2, varscan2
- TESMIN | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 113/303 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs752773586, COSV99663276; called by muse, mutect2, varscan2
- THSD7A | c.4233C>A p.C1411* | Nonsense Mutation (SNP) | VAF 63/221 reads (29%) | catalogued as COSV69855600; called by muse, mutect2, varscan2
- TMEM250 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 158/407 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1391144471; called by muse, mutect2, varscan2
- TRIM59 | c.1207C>T p.H403Y | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100557494; called by muse, mutect2, varscan2
- TTI2 | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 93/223 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs753940173; called by muse, mutect2, varscan2
- TTN | c.34288G>A p.E11430K (on ENST00000591111; = p.E12493K on NM_001267550.2) | Missense Mutation (SNP) | VAF 86/501 reads (17%) | PolyPhen benign (0); catalogued as rs1426948805, COSV100616895, COSV100634842; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTYH3 | c.1030C>T p.L344F | Missense Mutation (SNP) | VAF 143/416 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.408); catalogued as rs762035823; called by muse, mutect2, varscan2
- UBA7 | c.811C>A p.L271M | Missense Mutation (SNP) | VAF 137/410 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.77); catalogued as rs1559436911; called by muse, mutect2, varscan2
- UTP15 | c.601C>T p.L201F | Missense Mutation (SNP) | VAF 154/384 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.238); catalogued as rs780107230, COSV57140772; called by muse, mutect2, varscan2
- VCAN | c.4378G>A p.E1460K | Missense Mutation (SNP) | VAF 112/377 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV54102865; called by muse, mutect2, varscan2
- ZBED2 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 223/552 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs375389645; called by muse, mutect2, varscan2
- ZBTB14 | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 188/474 reads (40%) | catalogued as COSV63696818; called by muse, mutect2, varscan2
- ZFHX4 | c.8414C>T p.S2805L | Missense Mutation (SNP) | VAF 172/442 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50501474; called by muse, mutect2, varscan2
- ZNF106 | c.1744C>T p.Q582* | Nonsense Mutation (SNP) | VAF 120/316 reads (38%) | catalogued as COSV55516020; called by muse, mutect2, varscan2
- ZNF765 | c.1378C>T p.H460Y | Missense Mutation (SNP) | VAF 111/316 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV67183076; called by muse, varscan2
- ABCA13 | c.9764C>T p.S3255L | Missense Mutation (SNP) | VAF 147/400 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- AC099489.1 | c.3862G>A p.E1288K | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACACA | c.4978C>T p.P1660S | Missense Mutation (SNP) | VAF 183/473 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ACSM1 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 114/400 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AGTPBP1 | c.2869C>T p.P957S (on ENST00000357081 / NM_001330701.2; = p.P917S on NM_015239.2) | Missense Mutation (SNP) | VAF 92/232 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ANGPTL3 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 86/205 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- APOB | c.1793C>T p.A598V | Missense Mutation (SNP) | VAF 121/330 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- APOH | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 90/290 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARAP2 | c.5075C>T p.T1692I | Missense Mutation (SNP) | VAF 67/257 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF38 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ARSJ | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 125/379 reads (33%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- ASXL2 | c.3389C>T p.T1130I | Missense Mutation (SNP) | VAF 113/315 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATP2B1 | c.1539T>G p.Y513* | Nonsense Mutation (SNP) | VAF 64/162 reads (40%) | called by muse, mutect2, varscan2
- ATXN2L | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 96/353 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- BAHCC1 | c.797G>A p.G266D | Missense Mutation (SNP) | VAF 208/478 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- BCL2L10 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 103/297 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- BSN | c.5573G>A p.R1858K | Missense Mutation (SNP) | VAF 222/598 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BUD13 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 143/400 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C6 | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 88/245 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- C8orf34 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 89/231 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CAND1 | c.3193G>T p.E1065* | Nonsense Mutation (SNP) | VAF 74/179 reads (41%) | called by muse, mutect2, varscan2
- CCDC168 | c.16385T>C p.L5462P | Missense Mutation (SNP) | VAF 127/436 reads (29%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CD34 | c.901C>A p.L301M | Missense Mutation (SNP) | VAF 162/447 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CERS3 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 150/430 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLDN4 | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 277/665 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- CLEC14A | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 184/536 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- CLSTN3 | c.1765G>C p.A589P | Missense Mutation (SNP) | VAF 167/312 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CNTN1 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTNAP3 | c.2927G>A p.R976K | Missense Mutation (SNP) | VAF 134/415 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL3A1 | c.2707G>A p.G903R | Missense Mutation (SNP) | VAF 142/376 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- COL4A4 | c.1979G>A p.G660D | Missense Mutation (SNP) | VAF 117/306 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A6 | c.4201G>A p.G1401R | Missense Mutation (SNP) | VAF 142/402 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPS3 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 111/295 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- CORIN | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 142/357 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- CR1 | c.3880G>A p.G1294S | Missense Mutation (SNP) | VAF 103/275 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD1 | c.7432C>T p.P2478S (on ENST00000520002; = p.P2477S on NM_033225.6) | Missense Mutation (SNP) | VAF 110/210 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CYP4B1 | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 122/308 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DAOA | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 177/425 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DDX4 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 139/368 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DELE1 | c.1376T>A p.L459* | Nonsense Mutation (SNP) | VAF 163/416 reads (39%) | called by muse, mutect2, varscan2
- DELE1 | c.1377G>T p.L459F | Missense Mutation (SNP) | VAF 164/419 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DHX16 | c.2684C>T p.S895F | Missense Mutation (SNP) | VAF 187/509 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- DISP1 | c.1964T>C p.V655A | Missense Mutation (SNP) | VAF 126/329 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- DNAH5 | c.7012G>A p.D2338N | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- DNAH9 | c.7891C>T p.L2631F | Missense Mutation (SNP) | VAF 144/374 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- DNAJC13 | c.5344C>G p.R1782G | Missense Mutation (SNP) | VAF 109/277 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPF3 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 125/297 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- DPYSL2 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 143/397 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- DSCAM | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 136/394 reads (35%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- EFCAB6 | c.1955G>A p.G652E | Missense Mutation (SNP) | VAF 110/343 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- EML1 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 111/326 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- FAM160A2 | c.1922C>T p.S641L (on ENST00000449352 / NM_001098794.2; = p.S655L on NM_032127.4) | Missense Mutation (SNP) | VAF 188/465 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM166B | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 157/427 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- FANCA | c.1535C>T p.S512L | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- FAT4 | c.3143C>T p.P1048L | Missense Mutation (SNP) | VAF 155/443 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FER1L5 | c.1651G>A p.D551N (on ENST00000623019; = p.D556N on NM_001293083.2) | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FHL1 | c.488T>C p.V163A | Missense Mutation (SNP) | VAF 150/209 reads (72%) | SIFT tolerated (0.34); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- FLNA | c.2674C>T p.P892S | Missense Mutation (SNP) | VAF 157/213 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- FLNC | c.7264A>T p.K2422* | Nonsense Mutation (SNP) | VAF 166/412 reads (40%) | called by muse, mutect2, varscan2
- FOXO1 | c.998C>T p.T333I | Missense Mutation (SNP) | VAF 127/376 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- FSIP2 | c.18289G>A p.G6097R | Missense Mutation (SNP) | VAF 100/274 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GIMAP8 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 136/415 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GJD2 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GLDN | c.925A>G p.N309D | Missense Mutation (SNP) | VAF 110/279 reads (39%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- GLI2 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 109/290 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- GLI2 | c.2324C>T p.S775F (on ENST00000361492 / NM_001374353.1; = p.S792F on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 228/587 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- GNAT1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 138/342 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GNB1L | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 186/467 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIP1 | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 126/351 reads (36%) | called by muse, mutect2, varscan2
- HCST | c.211T>C p.C71R | Missense Mutation (SNP) | VAF 150/435 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HLA-DOB | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 180/456 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- IDO2 | c.1205T>A p.I402N (on ENST00000389060; = p.I415N on NM_194294.2) | Missense Mutation (SNP) | VAF 87/250 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- IGHV4-61 | c.204G>A p.W68* | Nonsense Mutation (SNP) | VAF 134/300 reads (45%) | called by muse, varscan2
- IGKV1-9 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 124/389 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- ITGAL | c.537G>A p.M179I | Missense Mutation (SNP) | VAF 133/345 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- ITIH1 | c.540_545del p.V181_K182del | In Frame Del (DEL) | VAF 114/339 reads (34%) | called by mutect2, pindel, varscan2
- JAML | c.358C>T p.L120F (on ENST00000356289 / NM_001098526.2; = p.L110F on NM_153206.3) | Missense Mutation (SNP) | VAF 145/412 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- KALRN | c.2605C>T p.H869Y | Missense Mutation (SNP) | VAF 134/400 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KBTBD8 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 181/423 reads (43%) | called by muse, mutect2, varscan2
- KIAA2012 | c.2096G>A p.R699K | Missense Mutation (SNP) | VAF 117/321 reads (36%) | SIFT tolerated (0.56); called by muse, mutect2, varscan2
- KIF18A | c.2678C>T p.S893L | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KIF27 | c.1823C>A p.P608Q | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); called by mutect2, varscan2
- KLHL13 | c.1322G>A p.G441E | Missense Mutation (SNP) | VAF 140/193 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- KNL1 | c.5515A>G p.N1839D (on ENST00000346991 / NM_170589.5; = p.N1813D on NM_144508.5) | Missense Mutation (SNP) | VAF 150/407 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- LAMA1 | c.7153G>A p.G2385R | Missense Mutation (SNP) | VAF 121/349 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA3 | c.1665T>G p.C555W | Missense Mutation (SNP) | VAF 165/446 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- LIN54 | c.1724A>T p.N575I | Missense Mutation (SNP) | VAF 94/252 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LMO7 | c.4733C>T p.S1578F (on ENST00000357063; = p.S1259F on NM_005358.5) | Missense Mutation (SNP) | VAF 110/400 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- LMTK2 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 174/466 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- LPP | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 180/501 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- LRRN4 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 188/497 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MALRD1 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 99/158 reads (63%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MAML2 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 163/524 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2
- MINDY4 | c.1582A>G p.K528E | Missense Mutation (SNP) | VAF 176/378 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- MMP19 | c.306C>T p.G102= | Splice Region (SNP) | VAF 83/227 reads (37%) | called by muse, mutect2, varscan2
- MROH1 | c.3091C>T p.L1031F | Missense Mutation (SNP) | VAF 152/574 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MUC17 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 163/509 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- MUC5B | c.10429G>A p.G3477S | Missense Mutation (SNP) | VAF 293/836 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUSK | c.1057C>T p.H353Y | Missense Mutation (SNP) | VAF 154/451 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- MXRA5 | c.4574C>T p.S1525F | Missense Mutation (SNP) | VAF 189/248 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- MYBPC1 | c.2951A>C p.H984P (on ENST00000550270 / NM_206820.2; = p.H991P on NM_002465.4) | Missense Mutation (SNP) | VAF 75/244 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH7B | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 150/480 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NALCN | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 103/262 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NASP | c.899T>G p.L300* | Nonsense Mutation (SNP) | VAF 181/514 reads (35%) | called by muse, mutect2, varscan2
- NBN | c.1475A>C p.Q492P | Missense Mutation (SNP) | VAF 140/351 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- NCAPH | c.722T>C p.I241T | Missense Mutation (SNP) | VAF 102/300 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- NEBL | c.1294C>T p.L432F | Missense Mutation (SNP) | VAF 133/209 reads (64%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- NFATC4 | c.2347C>T p.L783F | Missense Mutation (SNP) | VAF 228/638 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NLRP13 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 211/540 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NLRP5 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 124/383 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOBOX | c.636G>A p.M212I | Missense Mutation (SNP) | VAF 141/393 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOL10 | c.762A>C p.L254F | Missense Mutation (SNP) | VAF 100/293 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- OFD1 | c.2293C>T p.P765S | Missense Mutation (SNP) | VAF 160/194 reads (82%) | SIFT tolerated (0.27); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OR14I1 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR1G1 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 121/333 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR1P1 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 120/335 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- OR2A14 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 99/330 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR2AT4 | c.155T>G p.V52G | Missense Mutation (SNP) | VAF 177/449 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OR4D10 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 126/335 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OR4K3 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 102/644 reads (16%) | SIFT deleterious, low confidence (0.01); called by mutect2, varscan2
- OR5M11 | c.519_534del p.I173Mfs*67 | Frame Shift Del (DEL) | VAF 115/380 reads (30%) | called by mutect2, pindel, varscan2
- OSGEPL1 | c.879G>A p.M293I | Missense Mutation (SNP) | VAF 131/389 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGA7 | c.1718C>T p.T573I | Missense Mutation (SNP) | VAF 174/484 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- PCYT1B | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 228/303 reads (75%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDGFB | c.292A>C p.K98Q | Missense Mutation (SNP) | VAF 149/445 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDS5B | c.1889A>G p.D630G | Missense Mutation (SNP) | VAF 98/279 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- PES1 | c.21G>T p.K7N | Missense Mutation (SNP) | VAF 151/401 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by mutect2, varscan2
- PHF12 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 201/537 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKP1 | c.2057A>G p.N686S | Missense Mutation (SNP) | VAF 101/268 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLA2R1 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 103/333 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PMS2 | c.2398C>T p.P800S | Missense Mutation (SNP) | VAF 105/408 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- PPP1R2B | c.347T>A p.I116N | Missense Mutation (SNP) | VAF 134/341 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PRAMEF11 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 72/437 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- PRPS1L1 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 124/352 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PSD3 | c.2161A>C p.K721Q (on ENST00000440756; = p.K720Q on NM_015310.4) | Missense Mutation (SNP) | VAF 97/180 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- PTPRB | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 102/291 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- PTPRK | c.3721C>T p.P1241S (on ENST00000368215 / NM_001291984.2; = p.P1242S on NM_002844.4) | Missense Mutation (SNP) | VAF 84/263 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- RAI14 | c.2027T>A p.I676N | Missense Mutation (SNP) | VAF 117/282 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- RBP2 | c.267G>A p.W89* | Nonsense Mutation (SNP) | VAF 119/343 reads (35%) | called by muse, mutect2, varscan2
- RHOT1 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 77/225 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- RNF111 | c.2798_2809del p.G933_E936del (on ENST00000557998 / NM_001270530.1; = p.G925_E928del on NM_017610.8 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 67/332 reads (20%) | called by mutect2, pindel, varscan2
- RPS6KA3 | c.1577C>T p.T526I | Missense Mutation (SNP) | VAF 127/185 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- RRP12 | c.2505C>T p.P835= | Splice Region (SNP) | VAF 104/186 reads (56%) | called by muse, mutect2, varscan2
- RYR3 | c.2329C>T p.P777S | Missense Mutation (SNP) | VAF 101/293 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SATB1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 75/199 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- SCN4A | c.2926G>A p.D976N | Missense Mutation (SNP) | VAF 181/508 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- SCTR | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 115/353 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SETD1A | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 194/527 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- SF3B1 | c.3521A>G p.E1174G | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- SIGLEC5 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 104/287 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SIK3 | c.2489C>T p.P830L (on ENST00000445177 / NM_001366686.2; = p.P788L on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/315 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- SIN3B | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 121/229 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC10A2 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 134/372 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC15A5 | c.1001C>T p.T334I | Missense Mutation (SNP) | VAF 102/183 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC38A7 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 165/290 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC44A1 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 63/202 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPAG9 | c.3267G>T p.E1089D (on ENST00000262013 / NM_001130528.3; = p.E1075D on NM_003971.6) | Missense Mutation (SNP) | VAF 145/387 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SPEG | c.9403G>A p.G3135R | Missense Mutation (SNP) | VAF 122/370 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPEG | c.9404G>T p.G3135V | Missense Mutation (SNP) | VAF 122/369 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTBN1 | c.4760G>C p.R1587P | Missense Mutation (SNP) | VAF 161/430 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ST13 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 87/264 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ST3GAL2 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 27/441 reads (6%) | PolyPhen benign (0.162); called by muse, mutect2
- STARD9 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 99/278 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SULT2A1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 182/507 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SUSD3 | c.231G>A p.W77* | Nonsense Mutation (SNP) | VAF 190/494 reads (38%) | called by muse, mutect2, varscan2
- TACC2 | c.6985C>T p.P2329S (on ENST00000334433; = p.P407S on NM_006997.4) | Missense Mutation (SNP) | VAF 198/315 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- TBCCD1 | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 155/454 reads (34%) | called by muse, mutect2, varscan2
- TLK2 | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 129/347 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLR5 | c.1561G>A p.V521I | Missense Mutation (SNP) | VAF 191/504 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TM9SF4 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 123/379 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM119 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 156/478 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TMPRSS15 | c.648A>T p.E216D | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TNXB | c.6466G>A p.D2156N (on ENST00000647633; = p.D1909N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 131/385 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- TNXB | c.2645T>G p.V882G | Missense Mutation (SNP) | VAF 168/483 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TOX2 | c.1061G>A p.S354N (on ENST00000358131 / NM_001098798.2; = p.S330N on NM_032883.3) | Missense Mutation (SNP) | VAF 222/607 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TPSB2 | c.817A>G p.K273E | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TSC2 | c.3838C>T p.Q1280* | Nonsense Mutation (SNP) | VAF 15/499 reads (3%) | called by muse, mutect2
- TTN | c.89083G>A p.G29695R (on ENST00000591111; = p.G22271R on NM_003319.4) | Missense Mutation (SNP) | VAF 168/462 reads (36%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TUBA4A | c.773A>G p.N258S | Missense Mutation (SNP) | VAF 227/610 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- UNC13D | c.2298+1G>A p.X766_splice | Splice Site (SNP) | VAF 119/336 reads (35%) | called by muse, mutect2, varscan2
- WDR44 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 227/332 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WFDC8 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 169/426 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFYVE9 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 127/354 reads (36%) | called by muse, mutect2, varscan2
- ZNF208 | c.2983C>T p.H995Y | Missense Mutation (SNP) | VAF 86/166 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF286A | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 103/293 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ZNF366 | c.514A>C p.T172P | Missense Mutation (SNP) | VAF 193/572 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF620 | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 137/408 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ZNF792 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 165/456 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AHRR | c.790C>T p.L264= | Silent (SNP) | VAF 153/434 reads (35%) | called by muse, mutect2, varscan2
- ALDOC | c.61C>T p.L21= | Silent (SNP) | VAF 134/411 reads (33%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.3624C>T p.Y1208= (on ENST00000310343 / NM_001378025.1; = p.Y859= on NM_014715.4) | Silent (SNP) | VAF 111/329 reads (34%) | called by muse, mutect2, varscan2
- ASTN2 | c.2247C>T p.S749= (on ENST00000313400 / NM_001365069.1; = p.S698= on NM_014010.5) | Silent (SNP) | VAF 112/318 reads (35%) | catalogued as rs1215953513; called by muse, mutect2, varscan2
- ASTN2 | c.1863C>T p.L621= (on ENST00000313400 / NM_001365069.1; = p.L570= on NM_014010.5) | Silent (SNP) | VAF 116/343 reads (34%) | catalogued as rs749465987, COSV100526195; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATR | c.1803C>T p.S601= | Silent (SNP) | VAF 130/368 reads (35%) | called by muse, mutect2
- BACH1 | c.2178G>A p.Q726= | Silent (SNP) | VAF 90/244 reads (37%) | called by muse, mutect2, varscan2
- BRINP3 | c.1485C>T p.L495= | Silent (SNP) | VAF 113/336 reads (34%) | catalogued as rs768599124, COSV66524463; called by muse, mutect2, varscan2
- BSN | c.561C>T p.F187= | Silent (SNP) | VAF 174/507 reads (34%) | called by muse, mutect2, varscan2
- CCDC146 | c.678C>T p.V226= | Silent (SNP) | VAF 65/192 reads (34%) | called by muse, mutect2
- CCDC146 | c.679C>T p.L227= | Silent (SNP) | VAF 65/188 reads (35%) | catalogued as rs1361534987, COSV99592770; called by muse, mutect2
- CCDC173 | c.327G>A p.K109= | Silent (SNP) | VAF 90/241 reads (37%) | called by muse, mutect2, varscan2
- CCL15 | c.306G>A p.Q102= | Silent (SNP) | VAF 151/429 reads (35%) | called by muse, mutect2, varscan2
- CCNK | c.300C>T p.L100= | Silent (SNP) | VAF 83/220 reads (38%) | called by muse, mutect2, varscan2
- CD3D | c.186A>G p.K62= | Silent (SNP) | VAF 151/471 reads (32%) | called by muse, mutect2, varscan2
- CDH18 | c.1794G>A p.R598= | Silent (SNP) | VAF 188/515 reads (37%) | catalogued as rs1489399653; called by muse, mutect2, varscan2
- CFAP97 | c.1551C>T p.H517= | Silent (SNP) | VAF 125/354 reads (35%) | called by muse, varscan2
- CFHR5 | c.1119G>A p.G373= | Silent (SNP) | VAF 95/268 reads (35%) | catalogued as COSV56819664; called by muse, mutect2, varscan2
- CPA3 | c.228A>G p.Q76= | Silent (SNP) | VAF 98/289 reads (34%) | called by muse, mutect2, varscan2
- CROCC2 | c.2379C>T p.S793= | Silent (SNP) | VAF 112/342 reads (33%) | called by muse, mutect2, varscan2
- CTIF | c.1653G>A p.R551= | Silent (SNP) | VAF 199/510 reads (39%) | catalogued as rs1303244549; called by muse, mutect2, varscan2
- DLGAP1 | c.2028C>T p.S676= | Silent (SNP) | VAF 118/304 reads (39%) | catalogued as rs780984705, COSV59780862, COSV59831544; called by muse, varscan2
- DMBT1 | c.6303C>T p.S2101= (on ENST00000338354 / NM_001377530.1; = p.S1344= on NM_004406.3) | Silent (SNP) | VAF 122/220 reads (55%) | called by muse, mutect2, varscan2
- DNAH3 | c.4084C>T p.L1362= | Silent (SNP) | VAF 143/394 reads (36%) | catalogued as COSV54544739; called by muse, mutect2, varscan2
- DNAH5 | c.7473C>T p.S2491= | Silent (SNP) | VAF 227/585 reads (39%) | catalogued as rs1163482951; called by muse, mutect2, varscan2
- DNAH5 | c.6279C>T p.L2093= | Silent (SNP) | VAF 109/297 reads (37%) | called by muse, mutect2, varscan2
- DNAH9 | c.6360G>A p.V2120= | Silent (SNP) | VAF 116/355 reads (33%) | catalogued as rs867323566; called by muse, mutect2, varscan2
- DNAJA2 | c.483T>A p.A161= | Silent (SNP) | VAF 183/308 reads (59%) | called by muse, mutect2, varscan2
- DYTN | c.495C>T p.F165= | Silent (SNP) | VAF 126/380 reads (33%) | catalogued as rs370984067; called by muse, mutect2, varscan2
- EDC4 | c.429C>T p.S143= | Silent (SNP) | VAF 148/248 reads (60%) | called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2067C>T p.I689= | Silent (SNP) | VAF 179/424 reads (42%) | catalogued as rs750670890, COSV62567416; called by muse, mutect2, varscan2
- EPHA3 | c.1557G>A p.T519= | Silent (SNP) | VAF 148/374 reads (40%) | catalogued as COSV100343555; called by muse, varscan2
- EVPL | c.5832C>T p.L1944= | Silent (SNP) | VAF 184/563 reads (33%) | catalogued as COSV101440955; called by muse, mutect2, varscan2
- EWSR1 | c.1410C>T p.L470= | Silent (SNP) | VAF 88/257 reads (34%) | catalogued as rs1287559901; called by muse, mutect2, varscan2
- FAM135B | c.117G>A p.R39= | Silent (SNP) | VAF 172/605 reads (28%) | catalogued as COSV50522877; called by muse, mutect2, varscan2
- FAM186A | c.549C>T p.F183= | Silent (SNP) | VAF 104/286 reads (36%) | called by muse, mutect2
- FOXD2 | c.1029G>A p.S343= | Silent (SNP) | VAF 178/472 reads (38%) | called by muse, mutect2, varscan2
- GFOD1 | c.372C>T p.F124= | Silent (SNP) | VAF 202/517 reads (39%) | catalogued as COSV101014996; called by muse, mutect2, varscan2
- GLYCTK | c.642C>T p.T214= | Silent (SNP) | VAF 218/543 reads (40%) | called by muse, mutect2, varscan2
- GOLGA8S | c.1752G>A p.E584= | Silent (SNP) | VAF 190/574 reads (33%) | called by muse, mutect2, varscan2
- GPHN | c.411G>A p.G137= | Silent (SNP) | VAF 133/345 reads (39%) | catalogued as COSV100017430; called by muse, mutect2, varscan2
- GRHL2 | c.1629G>A p.R543= | Silent (SNP) | VAF 92/414 reads (22%) | catalogued as rs149801558; called by muse, mutect2, varscan2
- GRID2 | c.2103G>A p.R701= | Silent (SNP) | VAF 160/361 reads (44%) | catalogued as rs867391179; called by muse, mutect2, varscan2
- GTF2E1 | c.393C>T p.V131= | Silent (SNP) | VAF 107/321 reads (33%) | catalogued as COSV99382111; called by muse, mutect2, varscan2
- HDAC5 | c.1048C>A p.R350= | Silent (SNP) | VAF 111/326 reads (34%) | called by muse, mutect2, varscan2
- HDC | c.379C>T p.L127= | Silent (SNP) | VAF 114/308 reads (37%) | called by muse, mutect2, varscan2
- HEPH | c.1755G>A p.L585= (on ENST00000343002; = p.L318= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 154/217 reads (71%) | called by muse, mutect2, varscan2
- HLA-G | c.933C>T p.I311= | Silent (SNP) | VAF 147/361 reads (41%) | catalogued as rs778011464, COSV64405282; called by muse, mutect2, varscan2
- HMBOX1 | c.561C>T p.S187= | Silent (SNP) | VAF 87/282 reads (31%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.870C>T p.I290= | Silent (SNP) | VAF 119/339 reads (35%) | catalogued as COSV51445994; called by muse, mutect2, varscan2
- HS3ST4 | c.780G>A p.K260= | Silent (SNP) | VAF 116/331 reads (35%) | called by muse, mutect2, varscan2
- HTR1F | c.594G>A p.L198= | Silent (SNP) | VAF 98/271 reads (36%) | catalogued as COSV100138293; called by muse, mutect2, varscan2
- IFNL3 | c.387C>T p.I129= | Silent (SNP) | VAF 165/401 reads (41%) | catalogued as rs757574552; called by muse, mutect2, varscan2
- IGHV3-7 | c.183G>A p.G61= | Silent (SNP) | VAF 102/261 reads (39%) | catalogued as rs782591395; called by muse, mutect2, varscan2
- IGSF10 | c.3042G>A p.R1014= | Silent (SNP) | VAF 158/385 reads (41%) | catalogued as rs766931700, COSV56781415; called by muse, mutect2, varscan2
- IL16 | c.3834C>T p.V1278= (on ENST00000302987 / NM_172217.5; = p.V577= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 100/291 reads (34%) | catalogued as rs757239392; called by muse, mutect2, varscan2
- IL27 | c.355C>T p.L119= | Silent (SNP) | VAF 136/449 reads (30%) | catalogued as COSV60490720; called by muse, mutect2, varscan2
- ITGA2 | c.2853C>T p.I951= | Silent (SNP) | VAF 83/252 reads (33%) | called by muse, mutect2, varscan2
- ITGA4 | c.2892G>A p.L964= | Silent (SNP) | VAF 58/187 reads (31%) | called by muse, mutect2, varscan2
- KCNV1 | c.759C>T p.F253= | Silent (SNP) | VAF 379/691 reads (55%) | catalogued as COSV52085444; called by muse, mutect2, varscan2
- KIAA2012 | c.3108C>T p.A1036= | Silent (SNP) | VAF 193/577 reads (33%) | called by muse, mutect2, varscan2
- KIF1A | c.4674C>T p.A1558= (on ENST00000320389 / NM_001379639.1; = p.A1550= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 190/553 reads (34%) | catalogued as COSV57497459; called by muse, mutect2, varscan2
- KIR2DL3 | c.807C>T p.C269= | Silent (SNP) | VAF 111/299 reads (37%) | catalogued as rs567830523; called by muse, mutect2, varscan2
- KIR3DL1 | c.345C>T p.I115= | Silent (SNP) | VAF 123/356 reads (35%) | catalogued as rs1459691268; called by muse, mutect2, varscan2
- KIR3DL3 | c.18C>T p.V6= | Silent (SNP) | VAF 154/479 reads (32%) | called by muse, mutect2, varscan2
- KLHL25 | c.1563T>C p.I521= | Silent (SNP) | VAF 175/475 reads (37%) | called by muse, mutect2, varscan2
- LMO7 | c.4734C>T p.S1578= (on ENST00000357063; = p.S1259= on NM_005358.5) | Silent (SNP) | VAF 110/398 reads (28%) | called by muse, mutect2, varscan2
- LRP1B | c.10323C>T p.F3441= | Silent (SNP) | VAF 105/299 reads (35%) | catalogued as COSV101253903; called by muse, mutect2, varscan2
- MACC1 | c.573C>A p.S191= | Silent (SNP) | VAF 139/376 reads (37%) | called by muse, varscan2
- MAGI2 | c.3219G>A p.V1073= | Silent (SNP) | VAF 122/272 reads (45%) | called by muse, mutect2, varscan2
- MAML2 | c.471C>T p.P157= | Silent (SNP) | VAF 166/530 reads (31%) | catalogued as rs1047342515, COSV73263782; called by muse, mutect2
- MAP4K4 | c.1068C>T p.F356= | Silent (SNP) | VAF 117/320 reads (37%) | catalogued as COSV100155201; called by muse, mutect2, varscan2
- MAST4 | c.2364A>T p.P788= (on ENST00000403625 / NM_001164664.2; = p.P599= on NM_015183.3) | Silent (SNP) | VAF 119/360 reads (33%) | called by muse, mutect2, varscan2
- MFAP1 | c.1299C>T p.A433= | Silent (SNP) | VAF 113/307 reads (37%) | catalogued as rs1312822416; called by muse, mutect2, varscan2
- MTHFD1 | c.147C>T p.S49= | Silent (SNP) | VAF 110/394 reads (28%) | catalogued as rs1397322331; called by muse, mutect2, varscan2
- MUC16 | c.28149C>T p.T9383= | Silent (SNP) | VAF 166/282 reads (59%) | catalogued as rs775203092; called by muse, mutect2, varscan2
- MUC16 | c.21318C>T p.T7106= | Silent (SNP) | VAF 172/272 reads (63%) | catalogued as COSV101202282; called by muse, mutect2, varscan2
- MUC2 | c.1587C>T p.F529= | Silent (SNP) | VAF 151/398 reads (38%) | called by muse, mutect2, varscan2
- MYCL | c.147C>T p.P49= (on ENST00000372816 / NM_001033081.3; = p.P79= on NM_005376.5) | Silent (SNP) | VAF 217/591 reads (37%) | catalogued as rs757202982; called by muse, mutect2, varscan2
- MYO15A | c.2538G>A p.P846= | Silent (SNP) | VAF 216/561 reads (39%) | catalogued as rs1463694356, COSV52761152; called by muse, mutect2, varscan2
- NLRP8 | c.2355C>T p.S785= | Silent (SNP) | VAF 158/365 reads (43%) | called by muse, mutect2, varscan2
- NPC2 | c.234G>T p.L78= | Silent (SNP) | VAF 148/440 reads (34%) | called by muse, mutect2, varscan2
- OBSCN | c.3450C>T p.G1150= | Silent (SNP) | VAF 101/307 reads (33%) | catalogued as COSV52811183; called by muse, mutect2, varscan2
- ONECUT2 | c.1380C>T p.S460= | Silent (SNP) | VAF 160/506 reads (32%) | called by muse, mutect2, varscan2
- OR10Q1 | c.198C>T p.F66= | Silent (SNP) | VAF 176/474 reads (37%) | catalogued as COSV57472038; called by muse, mutect2, varscan2
- OR13C8 | c.207C>T p.L69= | Silent (SNP) | VAF 156/458 reads (34%) | catalogued as COSV58611362; called by muse, mutect2, varscan2
- OR2A25 | c.210C>T p.I70= | Silent (SNP) | VAF 210/572 reads (37%) | catalogued as rs746269504, COSV68716976; called by muse, mutect2
- OR51Q1 | c.630C>T p.I210= | Silent (SNP) | VAF 93/260 reads (36%) | catalogued as rs773847387, COSV56178359; called by muse, mutect2, varscan2
- OR51V1 | c.903G>A p.Q301= | Silent (SNP) | VAF 81/248 reads (33%) | catalogued as rs965835299; called by muse, mutect2, varscan2
- OR5B12 | c.303C>T p.F101= | Silent (SNP) | VAF 193/517 reads (37%) | called by muse, mutect2, varscan2
- OR5D13 | c.777C>T p.F259= | Silent (SNP) | VAF 160/440 reads (36%) | catalogued as COSV62332974; called by muse, mutect2, varscan2
- OR5I1 | c.192C>T p.F64= | Silent (SNP) | VAF 131/403 reads (33%) | catalogued as COSV56885704; called by muse, mutect2
- OR6C6 | c.315G>A p.P105= | Silent (SNP) | VAF 129/344 reads (38%) | catalogued as rs751973071; called by muse, mutect2, varscan2
- OR6C75 | c.909C>T p.V303= | Silent (SNP) | VAF 76/252 reads (30%) | catalogued as COSV100595431, COSV58553058; called by muse, mutect2, varscan2
- OR8B2 | c.87C>T p.F29= | Silent (SNP) | VAF 142/452 reads (31%) | catalogued as COSV66664913; called by muse, varscan2
- OR9Q2 | c.655C>T p.L219= | Silent (SNP) | VAF 137/437 reads (31%) | catalogued as COSV61112903; called by muse, mutect2, varscan2
- OSR1 | c.120C>T p.N40= | Silent (SNP) | VAF 214/573 reads (37%) | catalogued as rs373968597; called by muse, mutect2, varscan2
- PDE1B | c.636G>A p.E212= | Silent (SNP) | VAF 112/356 reads (31%) | called by muse, mutect2, varscan2
- PEG3 | c.603G>A p.A201= | Silent (SNP) | VAF 125/361 reads (35%) | catalogued as rs759512604, COSV55639049; called by muse, mutect2, varscan2
- PITPNM1 | c.1575C>T p.S525= | Silent (SNP) | VAF 214/570 reads (38%) | called by muse, mutect2, varscan2
- PRAMEF12 | c.423G>A p.G141= | Silent (SNP) | VAF 154/396 reads (39%) | catalogued as COSV100743178; called by muse, mutect2, varscan2
- PRDM9 | c.1269A>G p.K423= | Silent (SNP) | VAF 152/411 reads (37%) | called by muse, mutect2, varscan2
- PTPRB | c.5508C>T p.S1836= | Silent (SNP) | VAF 96/262 reads (37%) | catalogued as rs375405938; called by muse, mutect2, varscan2
- PTPRC | c.492C>T p.S164= | Silent (SNP) | VAF 186/543 reads (34%) | catalogued as rs1053467525; called by muse, mutect2, varscan2
- RALGPS1 | c.123C>T p.A41= | Silent (SNP) | VAF 150/388 reads (39%) | catalogued as rs752100811, COSV99401002; called by muse, mutect2, varscan2
- RASSF10 | c.1311C>T p.H437= | Silent (SNP) | VAF 117/375 reads (31%) | called by muse, mutect2, varscan2
- RP1 | c.2793C>T p.F931= | Silent (SNP) | VAF 74/232 reads (32%) | called by muse, varscan2
- RUSF1 | c.1281G>A p.L427= | Silent (SNP) | VAF 143/390 reads (37%) | called by muse, mutect2, varscan2
- SAMD7 | c.555G>A p.R185= | Silent (SNP) | VAF 150/369 reads (41%) | catalogued as COSV100156817; called by muse, mutect2, varscan2
- SAMSN1 | c.663C>T p.V221= | Silent (SNP) | VAF 138/441 reads (31%) | catalogued as rs1427083479; called by muse, mutect2, varscan2
- SAMSN1 | c.75G>A p.G25= | Silent (SNP) | VAF 103/276 reads (37%) | called by muse, mutect2, varscan2
- SBK1 | c.798C>T p.F266= | Silent (SNP) | VAF 179/459 reads (39%) | catalogued as rs780295201, COSV59396153; called by muse, mutect2, varscan2
- SCN10A | c.2728C>T p.L910= | Silent (SNP) | VAF 134/366 reads (37%) | called by muse, mutect2, varscan2
- SCN9A | c.2991G>A p.K997= (on ENST00000303354; = p.K986= on NM_002977.3) | Silent (SNP) | VAF 111/278 reads (40%) | called by muse, mutect2, varscan2
- SCTR | c.276C>T p.F92= | Silent (SNP) | VAF 117/356 reads (33%) | catalogued as COSV50027415, COSV99191561; called by muse, mutect2, varscan2
- SDS | c.573C>T p.I191= | Silent (SNP) | VAF 175/519 reads (34%) | catalogued as rs146027909; called by muse, mutect2, varscan2
- SFPQ | c.462G>A p.P154= | Silent (SNP) | VAF 230/633 reads (36%) | called by muse, mutect2, varscan2
- SIAH3 | c.597C>T p.F199= | Silent (SNP) | VAF 207/504 reads (41%) | called by muse, mutect2, varscan2
- SIGLEC1 | c.2910G>A p.T970= | Silent (SNP) | VAF 127/372 reads (34%) | catalogued as rs766203030, COSV52463330; called by muse, mutect2, varscan2
- SLC35G3 | c.672C>T p.F224= | Silent (SNP) | VAF 258/715 reads (36%) | called by muse, mutect2, varscan2
- SLC66A1 | c.651C>T p.Y217= | Silent (SNP) | VAF 152/448 reads (34%) | catalogued as rs111669548; called by muse, mutect2, varscan2
- SMCHD1 | c.4272C>T p.P1424= | Silent (SNP) | VAF 75/197 reads (38%) | called by muse, mutect2, varscan2
- SOX17 | c.564C>T p.F188= | Silent (SNP) | VAF 226/584 reads (39%) | called by muse, mutect2, varscan2
- SSRP1 | c.78C>T p.S26= | Silent (SNP) | VAF 123/364 reads (34%) | catalogued as rs368834293, COSV99555114; called by muse, mutect2, varscan2
- ST3GAL4 | c.117C>T p.I39= (on ENST00000392669 / NM_001254758.1; = p.I35= on NM_006278.3) | Silent (SNP) | VAF 120/325 reads (37%) | called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1308G>A p.G436= | Silent (SNP) | VAF 114/296 reads (39%) | catalogued as COSV50079911; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.681C>T p.F227= | Silent (SNP) | VAF 126/390 reads (32%) | catalogued as COSV52536771; called by muse, mutect2, varscan2
- ST8SIA4 | c.423C>A p.T141= | Silent (SNP) | VAF 125/385 reads (32%) | catalogued as COSV51514593; called by muse, mutect2, varscan2
- STEAP4 | c.837C>T p.F279= | Silent (SNP) | VAF 171/411 reads (42%) | called by muse, mutect2, varscan2
- SYT10 | c.837G>A p.R279= | Silent (SNP) | VAF 114/310 reads (37%) | catalogued as rs760778883, COSV57336955; called by muse, mutect2, varscan2
- TADA2B | c.522G>A p.E174= | Silent (SNP) | VAF 192/523 reads (37%) | catalogued as rs773561973; called by muse, mutect2, varscan2
- TBX2 | c.483C>T p.D161= | Silent (SNP) | VAF 169/496 reads (34%) | called by muse, mutect2, varscan2
- TBX5 | c.273G>T p.V91= | Silent (SNP) | VAF 90/285 reads (32%) | called by muse, mutect2, varscan2
- TECPR1 | c.1926C>T p.V642= | Silent (SNP) | VAF 204/475 reads (43%) | catalogued as rs1185568278; called by muse, mutect2, varscan2
- TECTA | c.987C>T p.H329= | Silent (SNP) | VAF 180/536 reads (34%) | called by muse, mutect2, varscan2
- THEMIS | c.1410G>A p.E470= | Silent (SNP) | VAF 193/559 reads (35%) | catalogued as rs373727149; called by muse, mutect2, varscan2
- TLL1 | c.1011C>T p.I337= | Silent (SNP) | VAF 109/276 reads (39%) | catalogued as rs541355348, COSV50306345; called by muse, mutect2, varscan2
- TMEM200A | c.1041G>A p.R347= | Silent (SNP) | VAF 148/404 reads (37%) | catalogued as rs267600808, COSV51651813; called by muse, mutect2, varscan2
- TMEM45A | c.570G>A p.Q190= | Silent (SNP) | VAF 68/218 reads (31%) | called by muse, mutect2, varscan2
- TRIM59 | c.1206C>T p.S402= | Silent (SNP) | VAF 47/130 reads (36%) | called by muse, mutect2, varscan2
- TTN | c.22893C>T p.I7631= (on ENST00000591111; = p.I6704= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 143/369 reads (39%) | catalogued as COSV60131278; called by muse, mutect2, varscan2
- TTN | c.2694G>A p.V898= (on ENST00000591111; = p.V852= on NM_003319.4) | Silent (SNP) | VAF 154/452 reads (34%) | called by muse, mutect2, varscan2
- UFL1 | c.933A>G p.A311= | Silent (SNP) | VAF 120/348 reads (34%) | catalogued as rs201921069; called by muse, mutect2, varscan2
- UGT3A1 | c.1038G>A p.V346= | Silent (SNP) | VAF 104/300 reads (35%) | catalogued as COSV57096608, COSV57103219; called by muse, mutect2, varscan2
- UGT3A2 | c.1479G>A p.L493= | Silent (SNP) | VAF 158/393 reads (40%) | called by muse, mutect2, varscan2
- VAT1L | c.1254C>T p.I418= | Silent (SNP) | VAF 36/223 reads (16%) | catalogued as COSV100213482; called by muse, mutect2, varscan2
- VSTM4 | c.489C>T p.S163= | Silent (SNP) | VAF 102/165 reads (62%) | catalogued as COSV60527254; called by muse, mutect2, varscan2
- XIRP2 | c.9594G>A p.K3198= (on ENST00000628543; = p.K3373= on NM_152381.6) | Silent (SNP) | VAF 107/352 reads (30%) | called by muse, mutect2, varscan2
- ZNF318 | c.822C>T p.P274= | Silent (SNP) | VAF 146/427 reads (34%) | catalogued as rs1399395311, COSV100546552, COSV58937270; called by muse, mutect2, varscan2
- ZNF496 | c.1551G>A p.K517= | Silent (SNP) | VAF 149/411 reads (36%) | called by muse, mutect2, varscan2
- ZNF592 | c.3000C>T p.S1000= | Silent (SNP) | VAF 106/324 reads (33%) | called by muse, mutect2, varscan2
- ZNF622 | c.1272G>A p.Q424= | Silent (SNP) | VAF 135/400 reads (34%) | catalogued as COSV58074781; called by muse, mutect2, varscan2
- ZNF99 | c.1353A>G p.Q451= | Silent (SNP) | VAF 102/195 reads (52%) | catalogued as rs762077876; called by muse, mutect2, varscan2
- ZSCAN10 | c.136C>T p.L46= (on ENST00000252463; = p.L101= on NM_032805.3) | Silent (SNP) | VAF 176/566 reads (31%) | called by muse, mutect2, varscan2
- ZSCAN20 | c.2379C>T p.P793= | Silent (SNP) | VAF 147/435 reads (34%) | called by muse, mutect2, varscan2
- AC004551.1 | n.354-23205G>A | Intron (SNP) | VAF 111/341 reads (33%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840828 C>T | 5'Flank (SNP) | VAF 153/424 reads (36%) | called by muse, mutect2, varscan2
- ANAPC15 | chr11:72107587 G>A | 3'Flank (SNP) | VAF 140/353 reads (40%) | called by muse, mutect2, varscan2
- C2orf16 | chr2:27572960 G>A | 5'Flank (SNP) | VAF 128/332 reads (39%) | called by muse, mutect2, varscan2
- COL13A1 | c.1056+623G>A | Intron (SNP) | VAF 192/311 reads (62%) | called by muse, mutect2, varscan2
- DOCK10 | c.124-50686_124-50683del | Intron (DEL) | VAF 67/265 reads (25%) | called by mutect2, pindel, varscan2
- FCAR | c.649+57C>T | Intron (SNP) | VAF 36/101 reads (36%) | catalogued as rs763459285; called by muse, mutect2, varscan2
- FICD | c.302-166C>T | Intron (SNP) | VAF 134/392 reads (34%) | catalogued as rs777018004, COSV57209252; called by muse, mutect2, varscan2
- FUT9 | c.*7935G>A | 3'UTR (SNP) | VAF 131/409 reads (32%) | catalogued as rs759354841; called by muse, mutect2, varscan2
- GUCY1A2 | c.1836+29847C>T | Intron (SNP) | VAF 81/280 reads (29%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+27962C>T | Intron (SNP) | VAF 71/198 reads (36%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-12477C>T | Intron (SNP) | VAF 80/255 reads (31%) | catalogued as rs965938247; called by muse, mutect2, varscan2
- MAGEC3 | c.1124-182C>T | Intron (SNP) | VAF 197/248 reads (79%) | catalogued as COSV68924133; called by muse, mutect2, varscan2
- MGAM | c.4619-2056C>T | Intron (SNP) | VAF 168/234 reads (72%) | called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671181 C>T | 3'Flank (SNP) | VAF 105/260 reads (40%) | catalogued as rs763595431; called by muse, mutect2, varscan2
- PRORY | n.475C>T | RNA (SNP) | VAF 168/216 reads (78%) | called by muse, mutect2, varscan2
- RAB4A | chr1:229268883 G>A | 5'Flank (SNP) | VAF 100/287 reads (35%) | catalogued as rs1480330116; called by muse, mutect2, varscan2
- RN7SL495P | chr15:22607827 C>T | 3'Flank (SNP) | VAF 85/301 reads (28%) | called by muse, mutect2, varscan2
- SH2B1 | c.1898-223C>T | Intron (SNP) | VAF 227/555 reads (41%) | catalogued as rs760783965; called by muse, mutect2, varscan2
- TMEM104 | c.*2291A>G | 3'UTR (SNP) | VAF 169/422 reads (40%) | catalogued as rs763927858; called by muse, mutect2, varscan2
- TTN | c.34265-4238G>A | Intron (SNP) | VAF 52/444 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.10360+1357C>T | Intron (SNP) | VAF 125/381 reads (33%) | catalogued as rs373311410, COSV100618006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF225 | c.236-1791C>T | Intron (SNP) | VAF 150/370 reads (41%) | called by muse, mutect2, varscan2
